Surgical pathology report (de-identified scan), TCGA case TCGA-C5-A7X5, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Medical College of Wisconsin, specimen TCGA-C5-A7X5-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT - CONSULT

Patient Name: [REDACTED]
Address: [REDACTED]

Gender: F
DOB: [REDACTED] (Age: [REDACTED])

Physician(s): [REDACTED] M.D.

Service: [REDACTED]
Location: [REDACTED]
MRN: [REDACTED]
Hospital #: [REDACTED]
Patient Type: [REDACTED]

Accession #: [REDACTED]
Received: [REDACTED]
Reported: [REDACTED]

*ICD-O-3
Carcinoma, squamous cell
keratinizing NOS 8671/3
Site Cervix NOS 253.9
Q10101013*

DIAGNOSIS

UTERUS, ENDOMETRIUM, BIOPSY [REDACTED]
- DETACHED FRAGMENTS OF POORLY DIFFERENTIATED SQUAMOUS CELL CARCINOMA (SEE COMMENT)

UTERUS, ENDOCERVIX, CURETTAGE [REDACTED]
- POORLY DIFFERENTIATED SQUAMOUS CELL CARCINOMA

UTERUS, CERVIX, BIOPSY [REDACTED]
- POORLY DIFFERENTIATED SQUAMOUS CELL CARCINOMA

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

Report Electronically Reviewed and Signed Out By [REDACTED] M.D.

Microscopic Description and Comment

Histologic sections from all three specimens show poorly differentiated squamous cell carcinoma. The tumor has markedly pleomorphic nuclei, a high mitotic rate and exhibits extensive keratinization. In areas, there is a suggestion of cytoplasmic mucin but definitive glandular differentiation is not identified. In the endometrial biopsy only superficial tumor is identified, but stromal invasion is seen in the endocervical curettage and cervical biopsy specimens. No normal endometrial or endocervical tissue is identified in these specimens.

History

The patient is a [REDACTED] year old woman with postmenopausal bleeding, a pelvic mass and probable advanced stage cervical cancer.

Material(s) Received

Received are four slides labeled [REDACTED] and sublabeled A through D. These are derived from an endometrial biopsy (A), endocervical curettage (B), and cervical biopsies (C and D) performed on [REDACTED] as detailed in the accompanying corresponding pathology report. The material originates from [REDACTED] slides are returned to the submitting institution.

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

Physician Copy -
END OF REPORT

Reviewer Initials	SC	Case Reviewed: 1/2/13

Source: NCI Genomic Data Commons file 14c36877-eb57-419c-95d5-d2892d8b4b5b (TCGA-C5-A7X5.0807894B-043D-4074-85C4-6C7BFB2C8C54.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).